Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A8AF, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A8AF-01A (Primary Tumor).

[page 1 of 10]
Name :

Reg.No. :

Physician:

Sex : MALE

Age :

Consult :

Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

CLINICAL INFORMATION:

year old male with mesothelioma

OPERATION: Bronch, Pleurectomy, PDT

SPECIMEN: 1. Previous incision; 2. Right rib; 3. Visceral pleura; 4. Parietal pleura; 5. Previous biopsy site; 6. INTERcostal nerve; 7. INTERcostal nodes; 8. Pericardial fat; 9. Tumor; 10. Mediastinal parietal pleura; 11. Diaphragmatic pleura; 12. Interlobar lymph node; 13. Diaphragm; 14. Pericardial surface; 15. Hilar nodes; 16. Anterior chest wall; 17. Right chest wall; 18. Apical pleura; 19. Treated diaphragm; 20. Peritoneum; 21. Phrenic nerve; 22. Pericardial implant; 23. Pericardium; 24. Rib 8th; 25. Superior aspect old incision; 26. Posterior intercostal nodes; 27. Superior previous biopsy site

GROSS DESCRIPTION:

The specimen is received in formalin in 27 containers, each labeled with the patient's name and medical record number.

Specimen #1 is designated "previous incision" and consists of an elliptical portion of skin and underlying soft tissue. The skin surface measures 4.8 cm in length and 1.6 cm in width. The underlying soft tissue measures up to 2.2 cm from point of attachment. The skin surface is tan wrinkled and devoid of hair. There is a centrally located previous incision site measuring 0.8 cm in length and 0.1 cm in width. The site is grossly hemorrhagic and partially healed. The underlying soft tissue is tan yellow gray and homogenous. Representative sections are submitted in two cassettes labeled 1A and 1B.

Specimen #2 is designated "right rib" and consists of four segments of tan gray rib measuring from 5.2 to 6.0 cm. Each piece contains a small amount of adhered tan purple gray membranous soft tissue to its outer surface. Each segment is sectioned to show a homogenous cut surface. No suspicious lesions or abnormalities are grossly identified. Representative sections from each piece is submitted in two cassettes, 2A and 2B.

Specimen #3 is designated "visceral pleura" and consists of multiple fragments of tan purple gray membranous soft tissue with a small amount of adhered tan yellow gray adipose tissue measuring in aggregate 7.0 x 7.0 x 3.0 cm. Some of the pieces contain thickened area of yellow gray firm and rubbery soft tissue. Representative sections of these areas are submitted in two cassettes labeled 3A and 3B.

Name:

Page: 1

Continue...

[page 2 of 10]
Print Date

Accession #

Date of Birth:

Name

Reg.No.

Physician:

Sex : MALE

Age :

Consult :

Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

Specimen #4 is designated "parietal pleura" and consists of multiple fragments of tan purple gray membranous soft tissue with a small amount of adhered tan yellow gray adipose tissue measuring in aggregate 6.0 x 6.0 x 2.0 cm. Some of the pieces contain thickened area of yellow gray firm and rubbery soft tissue. Representative sections of these areas are submitted in two cassettes labeled 4A and 4B.

Verified - bx only. per

Specimen #5 is designated "previous biopsy site" and consists of a strip of tan pink and yellow gray soft tissue measuring 7.3 cm in length with a greatest diameter of 1.6 cm. The specimen has adhered underlying soft tissue measuring up to 2.5 cm from point of attachment. Sectioning through this specimen shows a tan yellow gray thickened cut surface and homogenous underlying soft tissue. Representative sections are submitted in two cassettes labeled 5A and 5B.

Specimen #6 is designated "intercostal nerve" and consists of multiple convoluted segments of tan pink and gray cylindrical soft tissue measuring in aggregate 2.0 x 2.0 x 0.5 cm. The specimen is submitted in toto in one cassette labeled #6.

Specimen #7 is designated "intercostal nodes" and consists of two tan yellow gray rubbery soft tissue fragments measuring 0.5 and 1.2 cm. The specimen is submitted in toto in one cassette labeled #7.

Specimen #8 is designated "pericardial fat" and consists of multiple fragments of tan yellow gray adipose tissue measuring in aggregate 10.0 x 10.0 x 5.0 cm. Sectioning through the specimen shows multiple focal areas of yellow gray firm and rubbery soft tissue nodules measuring up to 1.5 cm in greatest dimension. Representative sections of this area is submitted in two cassettes labeled 8A and 8B.

Specimen #9 is designated "tumor" and consists of a convoluted portion of tan pink and gray firm and rubbery soft tissue measuring 11.0 cm in length with a greatest diameter of 3.0 cm. The specimen is sectioned to show a tan yellow gray homogenous cut surface. Representative sections are submitted in two cassettes labeled 9A and 9B.

Specimen #10 is designated "mediastinal parietal pleura" and consists of of tan purple gray membranous soft tissue with a small amount of adhered tan yellow gray adipose tissue measuring in aggregate 9.0 x 9.0 x 3.0 cm. Some of

Name:

Page: 2

Continue...

[page 3 of 10]
Print Date
Accession ([REDACTED]
Date of Birth: [REDACTED]

Name : [REDACTED]
Reg.No. [REDACTED]
Physician:

Sex : MALE
Age :

Consult :
Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

the pieces contain thickened area of yellow gray firm and rubbery soft tissue. Representative sections of these areas are submitted in two cassettes labeled 10A and 10B.

Specimen #11 is designated "diaphragmatic pleura" and consists of multiple convoluted portions of tan pink and gray thickened soft tissue measuring in aggregate 4.0 x 4.0 x 1.0 cm. The specimen is sectioned to show a tan yellow gray homogenous cut surface. Representative sections are submitted in two cassettes 11A and 11B.

Specimen #12 is designated "interlobar lymph node" and consists of two purple gray rubbery portions of soft tissue measuring 1.0 and 1.3 cm. The specimen is submitted in toto in one cassette labeled #12.

Specimen #13 is designated "diaphragm" and consists of multiple fragments of tan purple gray membranous soft tissue with thickened areas of yellow gray firm and rubbery soft tissue measuring in aggregate 5.0 x 5.0 x 2.0 cm. The specimen is sectioned to show a tan reddish brown cut surface with thickened areas of yellow gray homogenous soft tissue. Representative sections are submitted in two cassettes 13A and 13B.

Specimen #14 is designated "pericardial surface" and consists of multiple fragments of tan purple gray rubbery soft tissue with a small amount of adhered tan yellow adipose tissue measuring in aggregate 2.0 x 2.0 x 1.0 cm. The specimen is sectioned to show a tan yellow gray homogenous cut surface with tan yellow gray firm and rubbery interlacing soft tissue. Representative section is submitted in one cassette labeled #14.

Specimen #15 is designated "hilar nodes" and consists of two tan purple gray rubbery portions of soft tissue measuring 0.5 and 1.2 cm. The specimen is submitted in toto in one cassette labeled #15.

Specimen #16 is designated "anterior chest wall" and consists of multiple fragments of tan yellow gray rubbery soft tissue measuring in aggregate 3.0 x 3.0 x 1.0 cm. The specimen is sectioned to show a homogenous cut surface. Representative sections are submitted in two cassettes labeled 16A and 16B.

Specimen #17 is designated "right chest wall" and consists of multiple fragments of tan yellow gray rubbery soft tissue measuring in aggregate 1.0 x 1.0 x 0.5 cm. The specimen is sectioned to show a tan yellow gray homogenous cut surface. Representative sections are submitted in one cassette labeled

Name: [REDACTED]

Page: 3
Continue...

[page 4 of 10]
Print Date
Accession
Date of Birth:

Name
Reg. No.
Physician:

Sex : MALE
Age :

Consult :
Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :
DATE RECEIVED IN LAB :

#17.

Specimen #18 is designated "apical pleura" and consists of multiple fragments of tan yellow gray rubbery soft tissue and tan purple gray convoluted membranous soft tissue measuring in aggregate 4.0 x 4.0 x 1.0 cm. The specimen is sectioned to show a tan yellow gray homogenous cut surface. Representative sections are submitted in two cassettes labeled 18A and 18B.

Specimen #19 is designated "treated diaphragm" and consists of multiple fragments of tan reddish brown soft tissue with interlacing yellow gray firm and rubbery soft tissue nodules measuring up to 1.8 cm. Soft tissue is sectioned to show homogenous cut surface. The nodule is sectioned to show a tan yellow gray cut surface. Representative sections of the yellow gray soft tissue is submitted in two cassettes 19A and 19B.

Specimen #20 is designated "peritoneum" and consists of a convoluted portion of purple gray membranous soft tissue measuring in aggregate 2.0 x 2.0 x 0.5 cm. The specimen is sectioned to show a homogenous cut surface. Representative section is submitted in one cassette labeled #20.

Specimen #21 is designated "phrenic nerve" and consists of a portion of tan pink and yellow gray cylindrical soft tissue measuring 21.0 cm in length with a greatest diameter of 0.2 cm. The specimen has a small amount of adhered tan yellow gray soft tissue to its outer surface. The specimen is submitted in toto in one cassette labeled #21.

Specimen #22 is designated "pericardial implant" and consists of three fragments of tan yellow gray rubbery soft tissue measuring from 0.5 to 1.6 cm. The specimen is submitted in toto in one cassette labeled #22.

Specimen #23 is designated "pericardium" and consists of multiple fragments of tan yellow gray rubbery soft tissue with admixed purple gray membranous soft tissue measuring in aggregate 4.0 x 4.0 x 1.0 cm. The specimen is sectioned to show a homogenous cut surface. Representative section is submitted in two cassettes 23A and 23B.

Specimen #24 is designated "rib 8th" and consists of three segments of tan pink and gray rib measuring from 4.5 to 7.0 cm. Each segment has a moderate amount of adhered purple gray membranous soft tissue and red brown soft tissue adhered to its outer surface. The smaller segment of rib is grossly asymmetrical and is discolored a lighter yellow gray. Sectioning through this

Name:

Page: 4
Continue...

[page 5 of 10]
Print Date :

Accession

Date of Birth:

Name

Reg.No.

Physician:

Sex : MALE

Age :

Consult :

Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

specimen shows a yellow gray to yellow brown cut surface (24B). The other two segments of rib are sectioned to show a homogenous cut surface. Representative sections are submitted in two cassettes as follows:

24A two larger segments of rib

24B representative section of smaller asymmetrical rib

Specimen #25 is designated "superior aspect old incision" and consists of a portion of tan pink and gray membranous soft tissue measuring 6.2 cm in length with a greatest diameter of 1.6 cm. The specimen is sectioned to show a red brown cut surface with thickened areas of yellow gray rubbery soft tissue. Representative sections are submitted in two cassettes 25A and 25B.

Specimen #26 is designated "posterior intercostal nodes" and consists of three tan yellow gray rubbery soft tissue fragments measuring 0.8 to 1.2 cm. The specimen is submitted in toto in one cassette labeled #26.

Specimen #27 is designated "superior previous biopsy site" and consists of an elliptical portion of skin and underlying soft tissue. The skin surface measures 8.7 cm in length and 2.1 cm in width. The underlying soft tissue measures up to 5.0 cm from point of attachment. The skin surface is tan gray wrinkled and devoid of hair. The specimen is sectioned to show a tan yellow gray homogenous underlying soft tissue. Representative section is submitted in two cassettes 27A and 27B.

This case was reviewed with
DICTATOR:

DATE:

SPECIAL STAINS PERFORMED TO AID IN THE INTERPRETATION OF THIS CASE:

CYTOKERATIN 7

CYTOKERATIN 20

DATE OF SURGERY :

DATE RECEIVED IN LAB :

MICROSCOPIC DIAGNOSIS:

1. PREVIOUS INCISION:

A fragment of skin showing fibrosis, chronic inflammation, fat necrosis and foci of giant cell reaction consistent with previous biopsy site.
No evidence of residual tumor in representative sections submitted

2. RIGHT RIB:

Fragments of benign lamellar bone containing unremarkable bone marrow

Name:

Page: 5

Continue...

[page 6 of 10]
Print Date
Accession
Date of Birth:

Name
Reg.No.
Physician:

Sex : MALE
Age :

Consult :
Copies

DATE OF SURGERY :
DATE RECEIVED IN LAB :

elements.

Adherent benign fibroadipose tissue and striated muscle.
Negative for malignancy.

3. VISCERAL PLEURA:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma, epithelioid type, see note.
Tumor focally invades the adherent underlying alveolar lung tissue.
Foci of lymphovascular invasion also identified.

4. PARIETAL PLEURA:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.
Foci of lymphovascular invasion also identified.

5. PREVIOUS BIOPSY SITE:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.

6. INTERCOSTAL NERVE

Benign fibroadipose tissue containing large nerve trunk.
Negative for malignancy.

7. INTERCOSTAL NODES:

Fragments of lymph node, no tumor seen.

8. PERICARDIAL FAT:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

9. TUMOR:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.
Foci of lymphovascular invasion also present.

10. MEDIASTINAL PARIETAL PLEURA:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.
Foci of lymphovascular invasion also present.

11. DIAPHRAGMATIC PLEURA:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.

[page 7 of 10]
Print Date

Accession: [REDACTED]

Date of Birth: [REDACTED]

Name: [REDACTED]

Reg. No. [REDACTED]

Physician: .

Sex : MALE

Age :

Consult :

Copies

DATE OF SURGERY :

DATE RECEIVED IN LAB :

Foci of lymphovascular invasion also present.

12. INTERLOBAR LYMPH NODE:

Fragments of lymph node, no tumor seen.

13. DIAPHRAGM:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.

Foci of lymphovascular invasion also present.

14. PERICARDIAL SURFACE:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

Foci of lymphovascular invasion also present.

15. HILAR NODES:

Fragments of nodular fibroadipose tissue containing few lymphoid tissue showing foci of malignant mesothelioma.

16. ANTERIOR CHEST WALL:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

17. RIGHT CHEST WALL:

Fragments of fibrous tissue showing foci of invasive malignant mesothelioma.

18. APICAL PLEURA:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

Few small nodular foci of hyalinized pleural plaque also noted.

19. TREATED DIAPHRAGM:

Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma.

Foci of lymphovascular invasion also present.

20. PERITONEUM:

Fragments of mesothelial cell lined fibroadipose tissue containing striated muscle.

Negative for malignancy.

21. PHRENIC NERVE:

Fibroadipose tissue containing large nerve showing few foci of malignant

Name: [REDACTED]

Page: 7

Continue...

[page 8 of 10]
Print Date

Accession: [REDACTED]

Date of Birth: [REDACTED]

Name [REDACTED]

Reg. No. [REDACTED]

Physician: [REDACTED]

Sex : MALE

Age :

Consult :

Copies

DATE OF SURGERY :

DATE RECEIVED IN LAB :

mesothelioma.

Tumor is only present within the fibroadipose tissue, but the nerve tissue itself is free of invasive tumor.

22. PERICARDIAL IMPLANT:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

23. PERICARDIUM:

Fragments of fibroadipose tissue showing foci of invasive malignant mesothelioma.

24. RIB STH:

Benign lamellar bone containing unremarkable bone marrow elements.

Benign cartilage, fibroadipose tissue and striated muscle.

Negative for malignancy.

25. SUPERIOR ASPECT OLD INCISION:

Fragments of benign fibroadipose tissue showing scant foci of invasive malignant mesothelioma.

Focus of embedded lamellar bone without evidence of invasion also present.

26. POSTERIOR INTERCOSTAL NODES:

Fragments of lymph node showing foci of metastatic malignant mesothelioma.

27. SUPERIOR PREVIOUS BIOPSY SITE:

Fragment of skin showing fibrosis, chronic inflammation, fat necrosis and focal giant cell reaction consistent with previous biopsy site.

No evidence of residual tumor in the representative sections submitted.

Note: Immunostains are performed on block #3A with adequate positive and negative controls. Tumor cells are positive for CK5/6, CK7, calretinin, D2-40 (membranous staining) and WT-1. Tumor cells are negative for CK20 and TTF-1. These features are consistent with malignant mesothelioma, see disclaimer.

Disclaimer

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug

[page 9 of 10]
Print Date
Accession #
Date of Birth:

Name
Reg. No.
Physician:

Sex : MALE
Age :

Consult :
Copies

DATE OF SURGERY :
DATE RECEIVED IN LAB :

Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IVO or IVO reagents were developed and their performance characteristics were validated for diagnostic use by the

. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that are not directly confirmed by routine histopathologic internal or external control specimens.

[page 10 of 10]
Print Date

Accession

Date of Birth:

Name

Reg. No.

Physician:

Sex : MALE

Age :

Consult :

Copies

DATE OF SURGERY :

DATE RECEIVED IN LAB :

PATHOLOGIST:

The case material was reviewed and the report
verified by:

(Electronic signature)

Name:

Page: 10

End of Report

Source: NCI Genomic Data Commons file 8af02fea-223c-45a2-90e2-0899d3c5eb6b (TCGA-TS-A8AF.7BB8D997-D3AB-4336-8B3C-D9D23AAA221C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).